Somatic mutation profile of tumor specimen TCGA-VS-A8EB-01A (aliquot TCGA-VS-A8EB-01A-11D-A36J-09) from TCGA case TCGA-VS-A8EB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 41.7 years (15,215 days).
Specimen TCGA-VS-A8EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc4053c3-d841-433d-a22f-73b27975b86a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EB-10A (Blood Derived Normal), aliquot TCGA-VS-A8EB-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27fa5537-87cc-4f3c-a1f2-8e7d27c280c7

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Nonsense Mutation 3, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.9676C>T p.Q3226* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101446993; called by muse, mutect2, varscan2
- ABCA8 | c.3569G>A p.R1190K | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1382132266, COSV99286074; called by muse, mutect2, varscan2
- ADCY2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.106); catalogued as rs576240306, COSV100601879, COSV57864504; called by muse, mutect2, varscan2
- ADGRA1 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as COSV101477349; called by muse, mutect2, varscan2
- ADGRB2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs372925356; called by muse, mutect2, varscan2
- AP5Z1 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV100804165; called by muse, mutect2, varscan2
- B3GALNT1 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV57581161; called by muse, mutect2, varscan2
- CCDC88A | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs992302494, COSV99710615; called by muse, mutect2, varscan2
- CFAP91 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as rs1010499390, COSV99847201; called by muse, mutect2, varscan2
- CTC1 | c.3046C>A p.L1016M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV100236516; called by muse, mutect2, varscan2
- DCAF12L1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64422227; called by muse, mutect2, varscan2
- DIDO1 | c.3404C>G p.S1135C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56621841, COSV99826181; called by muse, mutect2, varscan2
- EP300 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 143/161 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54325483, COSV54345374; called by muse, mutect2, varscan2
- EP400 | c.2700A>T p.R900S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as COSV100201399; called by muse, mutect2, varscan2
- EXT1 | c.1651C>G p.L551V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV100984036; called by muse, mutect2
- FAM193A | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100219297; called by muse, mutect2, varscan2
- FBXW5 | c.528C>G p.D176E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV99812536; called by muse, mutect2, varscan2
- HLCS | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200629955, COSV60795181; called by muse, mutect2, varscan2
- HYDIN | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs749971654, COSV100378303; called by muse, mutect2, varscan2
- INTS8 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100569313; called by muse, mutect2, varscan2
- KIF16B | c.3140C>T p.S1047L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100734455; called by muse, mutect2
- KLHL21 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.243); catalogued as COSV100887256; called by muse, mutect2, varscan2
- LIPH | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99956047; called by muse, mutect2, varscan2
- LRFN4 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV100540812, COSV58921388; called by muse, mutect2, varscan2
- MAP3K13 | c.1657A>G p.R553G | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV99407334; called by muse, mutect2, varscan2
- MAP3K6 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100709260; called by muse, mutect2, varscan2
- MSANTD2 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as rs768413495, COSV99515614; called by muse, mutect2, varscan2
- NOMO1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1310250376, COSV99814604; called by muse, mutect2, varscan2
- OR6C75 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.964); catalogued as rs760093042, COSV100595365, COSV58551084; called by muse, varscan2
- PAGR1 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100232709; called by muse, mutect2, varscan2
- PDE3A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV100762263; called by muse, mutect2
- PPFIA4 | c.2228C>T p.S743F (on ENST00000447715; = p.S744F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99690660; called by muse, mutect2, varscan2
- PPP2R3A | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.057); catalogued as rs376094878; called by muse, mutect2, varscan2
- PTPRK | c.4083G>A p.W1361* (on ENST00000368215 / NM_001291984.2; = p.W1362* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs754580293, COSV100951249; called by mutect2, varscan2
- RBM17 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV101159118; called by muse, mutect2
- REL | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99692153; called by muse, mutect2, varscan2
- REXO1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs373138200; called by muse, mutect2, varscan2
- SCN3A | c.3844G>A p.V1282I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.873); catalogued as COSV99327337; called by muse, mutect2, varscan2
- SLC35C2 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777413234, COSV99709383; called by muse, mutect2, varscan2
- SMG1 | c.9057G>C p.E3019D | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV101246203; called by muse, mutect2, varscan2
- SPHK2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs1412959058, COSV55334499; called by muse, mutect2, varscan2
- SPTB | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101072195; called by muse, mutect2, varscan2
- STAG1 | c.3385A>G p.M1129V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs759432131, COSV99365841; called by muse, mutect2, varscan2
- TFIP11 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 121/143 reads (85%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV101316473; called by muse, mutect2, varscan2
- TPRN | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58808093; called by muse, mutect2, varscan2
- TSHZ3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.257); catalogued as rs375404314, COSV53672746, COSV53680425; called by muse, varscan2
- TTK | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1005091833, COSV100036366; called by muse, mutect2, varscan2
- TXNRD1 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101423650; called by muse, mutect2
- VAMP8 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV99809170; called by muse, mutect2, varscan2
- WSCD2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.435); catalogued as COSV99774747; called by muse, mutect2, varscan2
- ZBTB46 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV55507716; called by muse, mutect2, varscan2
- ZNF135 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100536654; called by muse, mutect2, varscan2
- LCE4A | c.129_134del p.S44_S45del | In Frame Del (DEL) | VAF 3/26 reads (12%) | called by mutect2*, pindel
- LRP4 | c.1714_1726del p.D572Pfs*235 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel
- ABCC9 | c.1827C>T p.L609= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99685950; called by muse, mutect2
- BABAM2 | c.567C>G p.L189= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV59627000; called by muse, mutect2, varscan2
- CUX2 | c.3147G>A p.T1049= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs757600625, COSV55636299; called by muse, mutect2, varscan2
- DCAF12L1 | c.1233C>T p.L411= | Silent (SNP) | VAF 73/166 reads (44%) | catalogued as COSV64421312; called by muse, mutect2, varscan2
- DEXI | c.180C>T p.P60= | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as rs1466089642, COSV100081113; called by muse, mutect2, varscan2
- DNAJB5 | c.222C>T p.T74= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as rs765696926, COSV100257932; called by muse, mutect2, varscan2
- DUSP13 | c.85C>A p.R29= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs749493863, COSV100403515, COSV57815830; called by muse, mutect2, varscan2
- EML4 | c.2574C>T p.S858= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as COSV100580933; called by muse, mutect2, varscan2
- EPHA10 | c.1572C>T p.R524= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs777640555, COSV57626852; called by muse, mutect2, varscan2
- GALNTL5 | c.171C>A p.I57= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV101217845; called by muse, mutect2, varscan2
- GTPBP4 | c.555C>T p.I185= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV100672732; called by muse, mutect2, varscan2
- HCN3 | c.138G>A p.R46= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV100751883; called by muse, mutect2, varscan2
- HPS5 | c.562A>C p.R188= (on ENST00000349215 / NM_181507.2; = p.R74= on NM_007216.4) | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100834440; called by muse, mutect2, varscan2
- KCNN1 | c.369G>A p.T123= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs370392950; called by muse, mutect2, varscan2
- MICOS13 | c.108G>A p.K36= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs372429813; called by muse, mutect2, varscan2
- OR6C75 | c.672G>T p.L224= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100595363; called by muse, mutect2, varscan2
- SUB1 | c.225C>T p.R75= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs775792950, COSV99421654; called by muse, mutect2, varscan2
- TRPV5 | c.567C>T p.I189= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99520624, COSV99520799; called by muse, mutect2, varscan2
- ZNF568 | c.294C>T p.F98= | Silent (SNP) | VAF 56/594 reads (9%) | catalogued as COSV100451314; called by muse, mutect2
- SNORD116-23 | n.83A>G | RNA (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
